Somatic mutation profile of cancer-model specimen HCM-BROD-0356-C16-85A (3D Organoid, passage 5; aliquot HCM-BROD-0356-C16-85A-01D-A83U-36), derived from the primary tumor of HCMI case HCM-BROD-0356-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: G2; Age at diagnosis: 66.1 years (24,137 days).
Specimen HCM-BROD-0356-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0de64cb0-2f15-46e7-8ef4-538f039ad77d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0356-C16-10B (Blood Derived Normal), aliquot HCM-BROD-0356-C16-10B-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1328d922-c059-4341-9476-d60e3816a322

The open-access MAF lists 118 somatic variants for this specimen: 84 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 30, Frame Shift Del 10, Nonsense Mutation 5, In Frame Del 2, In Frame Ins 1, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1, Intron 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL1 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 199/403 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.085); catalogued as COSV69809028; called by muse, mutect2, varscan2
- ATG9A | c.100A>C p.K34Q | Missense Mutation (SNP) | VAF 36/600 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV60133926; called by muse, mutect2
- C1orf185 | c.212G>A p.C71Y | Missense Mutation (SNP) | VAF 124/280 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1393044386; called by muse, mutect2, varscan2
- ELOA2 | c.479T>C p.I160T | Missense Mutation (SNP) | VAF 41/358 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs151287064; called by muse, mutect2, varscan2
- EPHA4 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 89/549 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); catalogued as rs759721341, COSV56043854; called by muse, mutect2, varscan2
- ERRFI1 | c.1224A>C p.E408D | Missense Mutation (SNP) | VAF 237/548 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs1365672479, COSV66311595; called by muse, mutect2, varscan2
- FBXO43 | c.1321C>G p.P441A | Missense Mutation (SNP) | VAF 43/495 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1223449680; called by muse, mutect2
- GPRIN3 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 283/283 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs757846939, COSV60885151; called by muse, mutect2, varscan2
- IKBKB | c.1410T>A p.N470K | Missense Mutation (SNP) | VAF 22/626 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.566); catalogued as COSV104416108; called by muse, mutect2
- ITGA7 | c.3041C>T p.A1014V (on ENST00000555728; = p.A970V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 258/761 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs201354330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNA1 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 43/778 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV66837888; called by muse, mutect2
- KDM6A | c.4005+5_4005+8del p.X1335_splice | Splice Site (DEL) | VAF 110/130 reads (85%) | catalogued as rs886041946; called by pindel, varscan2
- MED23 | c.1219del p.E407Nfs*19 | Frame Shift Del (DEL) | VAF 133/186 reads (72%) | catalogued as COSV63436826; called by mutect2, pindel, varscan2
- MEGF9 | c.1403A>G p.N468S | Missense Mutation (SNP) | VAF 155/334 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as rs373252092; called by muse, mutect2, varscan2
- MYO5A | c.2545C>T p.R849* | Nonsense Mutation (SNP) | VAF 148/306 reads (48%) | catalogued as COSV100697277; called by muse, mutect2, varscan2
- PCDHB12 | c.2098C>T p.L700F | Missense Mutation (SNP) | VAF 22/800 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1554287109; called by muse, mutect2
- PGAP4 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 24/766 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as rs1281936849; called by muse, mutect2
- PMP22 | c.327C>G p.C109W | Missense Mutation (SNP) | VAF 38/480 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as CM041066, COSV56601983, COSV56603487; called by muse, mutect2
- PTPRZ1 | c.5546A>G p.Y1849C | Missense Mutation (SNP) | VAF 96/357 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1356187307; called by muse, mutect2, varscan2
- RASIP1 | c.1747G>A p.V583M | Missense Mutation (SNP) | VAF 547/1077 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs1408774763, COSV55804770; called by muse, mutect2, varscan2
- RIMS2 | c.1523G>A p.R508H (on ENST00000666250 / NM_001348490.2; = p.R316H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 256/480 reads (53%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV51669990; called by muse, varscan2
- SCN5A | c.1579G>A p.G527R | Missense Mutation (SNP) | VAF 261/554 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs763550164, COSV61140896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SFTPD | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 143/337 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100954508; called by muse, mutect2, varscan2
- SPTBN5 | c.9610C>T p.R3204C | Missense Mutation (SNP) | VAF 201/429 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as rs541049838; called by muse, mutect2, varscan2
- TEX15 | c.3018dup p.A1007Sfs*3 (on ENST00000256246; = p.A1390Sfs*3 on NM_001350162.2) | Frame Shift Ins (INS) | VAF 69/179 reads (39%) | catalogued as rs753315680; called by mutect2, varscan2
- TMEM94 | c.1232C>T p.T411M | Missense Mutation (SNP) | VAF 200/447 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760413205, COSV58600977; called by muse, mutect2, varscan2
- TRPV4 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 320/320 reads (100%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs1270661327; called by muse, varscan2
- UTP15 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as rs778348611; called by muse, mutect2, varscan2
- ACVR1C | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 26/555 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.111); called by muse, mutect2
- ADCY5 | c.3597G>A p.W1199* | Nonsense Mutation (SNP) | VAF 38/603 reads (6%) | called by muse, mutect2
- ADGRA3 | c.2800T>C p.Y934H | Missense Mutation (SNP) | VAF 255/481 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- AFF2 | c.1882A>G p.K628E | Missense Mutation (SNP) | VAF 18/399 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ALDH16A1 | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 44/734 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.374); called by muse, mutect2
- ARFRP1 | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 22/612 reads (4%) | called by muse, mutect2
- ATP1B1 | c.63_64insGAGTTTCTGGGCAGGACG p.K21_K22insEFLGRT | In Frame Ins (INS) | VAF 48/396 reads (12%) | called by mutect2, pindel, varscan2
- BBX | c.1619A>G p.K540R | Missense Mutation (SNP) | VAF 194/780 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- BRCA2 | c.9224T>A p.I3075K | Missense Mutation (SNP) | VAF 196/565 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C6orf132 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 20/682 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2
- CENPH | c.158_160del p.Q53del | In Frame Del (DEL) | VAF 62/206 reads (30%) | called by pindel, varscan2
- CUX1 | c.3326C>T p.S1109F | Missense Mutation (SNP) | VAF 32/994 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- DNM2 | c.505_526del p.S169Pfs*34 | Frame Shift Del (DEL) | VAF 186/490 reads (38%) | called by mutect2, pindel, varscan2
- DPP9 | c.983G>T p.G328V (on ENST00000598800; = p.G357V on NM_139159.5) | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.922); called by muse, mutect2
- ECPAS | c.4327G>T p.E1443* | Nonsense Mutation (SNP) | VAF 41/295 reads (14%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.2173G>C p.G725R | Missense Mutation (SNP) | VAF 54/562 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2
- ELMO2 | c.1748A>G p.D583G | Missense Mutation (SNP) | VAF 225/1092 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FBXO43 | c.1319C>A p.T440N | Missense Mutation (SNP) | VAF 43/498 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- GBP6 | c.1385G>T p.R462M | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); called by muse, mutect2
- HECTD1 | c.5948A>C p.Q1983P | Missense Mutation (SNP) | VAF 14/468 reads (3%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- HOXA6 | c.698A>T p.E233V | Missense Mutation (SNP) | VAF 23/342 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- ITGA6 | c.2548G>A p.G850R (on ENST00000442250; = p.G811R on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- LAPTM4B | c.418del p.D140Ifs*34 (on ENST00000445593; = p.D49Ifs*34 on NM_018407.6) | Frame Shift Del (DEL) | VAF 32/353 reads (9%) | called by mutect2, pindel
- LIM2 | c.476G>T p.C159F (on ENST00000596399 / NM_001161748.2; = p.C201F on NM_030657.4) | Missense Mutation (SNP) | VAF 18/694 reads (3%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- LIPT1 | c.500C>G p.S167C | Missense Mutation (SNP) | VAF 19/597 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- LMX1A | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 19/585 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- MST1 | c.2000del p.P667Lfs*27 | Frame Shift Del (DEL) | VAF 18/204 reads (9%) | called by mutect2, pindel
- NDC1 | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- NUBPL | c.88G>C p.A30P | Missense Mutation (SNP) | VAF 54/692 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.094); called by muse, mutect2
- NUP107 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 649/4329 reads (15%) | called by muse, mutect2, varscan2
- OR8J2 | c.920del p.N307Tfs*? | Frame Shift Del (DEL) | VAF 16/170 reads (9%) | called by mutect2, pindel
- OS9 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 54/974 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PDZD8 | c.429_435del p.S144Gfs*105 | Frame Shift Del (DEL) | VAF 75/431 reads (17%) | called by mutect2, pindel, varscan2
- PRRC2B | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 335/702 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTF1A | c.730G>C p.G244R | Missense Mutation (SNP) | VAF 68/269 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- RANBP2 | c.2669G>C p.R890T | Missense Mutation (SNP) | VAF 323/624 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- RB1 | c.1623_1642del p.N541Kfs*7 | Frame Shift Del (DEL) | VAF 66/76 reads (87%) | called by mutect2, pindel, varscan2
- REELD1 | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 308/308 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- RGPD3 | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RPE65 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 11/347 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.153); called by muse, mutect2
- RPS19 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 40/552 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- SALL1 | c.1505A>C p.K502T | Missense Mutation (SNP) | VAF 30/505 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SCN5A | c.1934C>G p.S645C | Missense Mutation (SNP) | VAF 42/885 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- SEC14L6 | c.185T>C p.F62S | Missense Mutation (SNP) | VAF 22/526 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- SEC14L6 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 18/520 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- SOS1 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPTB | c.6878T>C p.I2293T | Missense Mutation (SNP) | VAF 36/667 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.109); called by muse, mutect2
- TAPBPL | c.433A>G p.N145D | Missense Mutation (SNP) | VAF 24/502 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.395); called by muse, mutect2
- TPH1 | c.263_264del p.S88Cfs*6 | Frame Shift Del (DEL) | VAF 102/411 reads (25%) | called by pindel, varscan2
- TPRA1 | c.906G>T p.E302D | Missense Mutation (SNP) | VAF 70/790 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.01); called by muse, mutect2
- TRIM3 | c.29C>G p.P10R | Missense Mutation (SNP) | VAF 27/521 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- ZNF185 | c.305A>T p.Q102L | Missense Mutation (SNP) | VAF 240/240 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.163); called by muse, varscan2
- ZNF268 | c.1927_1929del p.N643del | In Frame Del (DEL) | VAF 26/268 reads (10%) | called by mutect2, pindel
- ZNF337 | c.149_152del p.S50* | Frame Shift Del (DEL) | VAF 40/198 reads (20%) | called by mutect2, pindel, varscan2
- ZNF717 | c.1710del p.K570Nfs*9 | Frame Shift Del (DEL) | VAF 83/296 reads (28%) | called by mutect2, pindel
- ZNF777 | c.1786C>A p.H596N | Missense Mutation (SNP) | VAF 38/1002 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, mutect2
- ARFGEF3 | c.2634C>T p.T878= | Silent (SNP) | VAF 205/205 reads (100%) | called by muse, mutect2, varscan2
- ASCC3 | c.5073G>C p.G1691= | Silent (SNP) | VAF 168/374 reads (45%) | called by muse, mutect2, varscan2
- ATP10A | c.177G>C p.L59= | Silent (SNP) | VAF 70/820 reads (9%) | called by muse, mutect2
- CNTN4 | c.921G>A p.R307= | Silent (SNP) | VAF 25/362 reads (7%) | catalogued as COSV61881812; called by muse, mutect2
- COL16A1 | c.4467T>C p.A1489= | Silent (SNP) | VAF 354/771 reads (46%) | called by muse, mutect2, varscan2
- DNM1L | c.181A>C p.R61= | Silent (SNP) | VAF 166/372 reads (45%) | called by muse, mutect2, varscan2
- ESPN | c.2118A>T p.T706= | Silent (SNP) | VAF 47/1020 reads (5%) | called by muse, mutect2
- GNA12 | c.63C>G p.R21= | Silent (SNP) | VAF 329/588 reads (56%) | called by mutect2, varscan2
- GPR150 | c.336G>A p.E112= | Silent (SNP) | VAF 92/972 reads (9%) | called by muse, mutect2
- GREB1 | c.3333G>A p.S1111= | Silent (SNP) | VAF 285/285 reads (100%) | catalogued as rs762601637, COSV52184969, COSV52193158; called by muse, varscan2
- H4C2 | c.162G>A p.E54= | Silent (SNP) | VAF 252/579 reads (44%) | catalogued as rs147907725, COSV99774681; called by muse, mutect2
- HID1 | c.736C>T p.L246= | Silent (SNP) | VAF 18/366 reads (5%) | catalogued as rs1240196718, COSV59352218; called by muse, mutect2
- LAMB2 | c.4504A>C p.R1502= | Silent (SNP) | VAF 262/262 reads (100%) | catalogued as rs1442587637, CD042872; called by muse, mutect2, varscan2
- LRFN3 | c.1050G>T p.T350= | Silent (SNP) | VAF 474/1025 reads (46%) | called by muse, mutect2, varscan2
- LRP1B | c.11565C>T p.S3855= | Silent (SNP) | VAF 122/278 reads (44%) | catalogued as rs1466698063; called by muse, mutect2, varscan2
- MYO9B | c.6201G>A p.T2067= | Silent (SNP) | VAF 413/883 reads (47%) | catalogued as rs770730753, COSV55726629; called by muse, mutect2, varscan2
- OS9 | c.105G>A p.E35= | Silent (SNP) | VAF 54/980 reads (6%) | catalogued as rs1298076920; called by muse, mutect2
- PCDHA9 | c.129C>A p.T43= | Silent (SNP) | VAF 54/943 reads (6%) | catalogued as COSV100968946; called by muse, mutect2
- PCDHB6 | c.1686G>A p.P562= | Silent (SNP) | VAF 440/1040 reads (42%) | catalogued as rs782507289, COSV50696238; called by muse, varscan2
- PKD1L1 | c.5808C>T p.F1936= | Silent (SNP) | VAF 236/469 reads (50%) | catalogued as COSV56965204; called by muse, mutect2, varscan2
- PLXNA2 | c.3012C>T p.I1004= | Silent (SNP) | VAF 32/586 reads (5%) | catalogued as rs772163887, COSV65443513; called by muse, mutect2
- PTF1A | c.729C>T p.G243= | Silent (SNP) | VAF 68/271 reads (25%) | called by muse, mutect2, varscan2
- RABL6 | c.100A>C p.R34= | Silent (SNP) | VAF 421/808 reads (52%) | called by muse, mutect2, varscan2
- RPRD1A | c.163A>C p.R55= | Silent (SNP) | VAF 100/100 reads (100%) | called by muse, mutect2, varscan2
- TNRC6A | c.4263G>A p.A1421= | Silent (SNP) | VAF 234/470 reads (50%) | catalogued as rs776856466; called by muse, mutect2, varscan2
- TOP2A | c.2106A>G p.E702= | Silent (SNP) | VAF 13/266 reads (5%) | called by muse, mutect2
- TTN | c.375G>C p.V125= | Silent (SNP) | VAF 209/485 reads (43%) | called by muse, mutect2, varscan2
- YARS2 | c.396G>A p.L132= | Silent (SNP) | VAF 40/1168 reads (3%) | catalogued as rs1200569501; called by muse, mutect2
- ZNF185 | c.309G>A p.Q103= | Silent (SNP) | VAF 238/238 reads (100%) | catalogued as rs781840827; called by muse, varscan2
- ZNF541 | c.972C>T p.H324= | Silent (SNP) | VAF 415/889 reads (47%) | catalogued as rs1452692447, COSV54542990; called by muse, mutect2, varscan2
- AC106038.2 | chr8:90703395 C>T | 3'Flank (SNP) | VAF 119/310 reads (38%) | catalogued as rs550318162; called by muse, mutect2, varscan2
- AC233702.8 | chr17:21551281 G>C | 5'Flank (SNP) | VAF 424/822 reads (52%) | called by muse, mutect2, varscan2
- CCSER2 | c.*620A>G | 3'UTR (SNP) | VAF 247/539 reads (46%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-32675C>A | Intron (SNP) | VAF 14/404 reads (3%) | called by muse, mutect2
